MMRF case MMRF_2140 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/24d247b5-90b8-4c21-a546-710da7756399

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 65 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 66.0 years (24,110 days); ISS stage: II; Days to last known disease status: 924 days (2.5 years); Days to last follow up: 924 days (2.5 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 90 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 132 days; Days to treatment end: 132 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 272 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -7 (ECOG 0): M Protein 3.18 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.69 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 7.09 mg/dL; Immunoglobulin G 35.9 g/L; Immunoglobulin A 0.31 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 2.44 µg/mL; Lactate Dehydrogenase 3.9 µkat/L; Hemoglobin 5.33 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 2.36 ×10⁹/L; Platelets 263 ×10⁹/L; Creatinine 62.8 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.15 mmol/L; Albumin 26 g/L; Total Protein 8.6 g/dL; Glucose 4.18 mmol/L; C-Reactive Protein 0.906 mg/dL.
- Day 92 (ECOG 0): M Protein 0.55 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.61 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.89 mg/dL; Immunoglobulin G 8.96 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.4 g/L; Beta 2 Microglobulin 1.56 µg/mL; Lactate Dehydrogenase 3.78 µkat/L; Hemoglobin 5.89 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.33 ×10⁹/L; Platelets 289 ×10⁹/L.
- Day 164 (ECOG 0): M Protein 0.16 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 6.88 g/L; Beta 2 Microglobulin 1.67 µg/mL; Lactate Dehydrogenase 6.13 µkat/L; Hemoglobin 5.89 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.04 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 38 µmol/L; Blood Urea Nitrogen 1.79 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 6.1 g/dL; Glucose 10.2 mmol/L.
- Day 248 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.08 mg/dL; Immunoglobulin G 4.98 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 1.62 µg/mL; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.38 ×10⁹/L; Platelets 213 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 6.6 g/dL; Glucose 5.83 mmol/L.
- Day 357: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.84 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.12 mg/dL; Immunoglobulin G 5.09 g/L; Immunoglobulin A 0.54 g/L; Immunoglobulin M 0.49 g/L; Beta 2 Microglobulin 1.61 µg/mL; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.42 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.48 mmol/L; Albumin 44 g/L; Total Protein 7.1 g/dL; Glucose 7.65 mmol/L.
- Day 482 (ECOG 0): Hemoglobin 6.45 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 6.3 g/dL; Glucose 6.49 mmol/L.
- Day 553: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.79 mg/dL; Immunoglobulin G 5.92 g/L; Immunoglobulin A 1.27 g/L; Immunoglobulin M 0.49 g/L; Beta 2 Microglobulin 1.54 µg/mL; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 2.75 ×10⁹/L; Platelets 208 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 6.4 g/dL; Glucose 13 mmol/L.
- Day 630 (ECOG 0): M Protein 0 g/dL; Immunoglobulin G 5.95 g/L; Immunoglobulin A 1.35 g/L; Immunoglobulin M 0.37 g/L; Hemoglobin 6.88 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 227 ×10⁹/L.
- Day 742 (ECOG 0): Hemoglobin 6.45 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 6.6 g/dL; Glucose 12.5 mmol/L.
- Day 833 (ECOG 0): M Protein 0 g/dL; Immunoglobulin G 6.59 g/L; Immunoglobulin A 1.38 g/L; Immunoglobulin M 0.5 g/L; Hemoglobin 6.14 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 212 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 6.2 g/dL; Glucose 12.7 mmol/L.
- Day 924 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.81 mg/dL; Immunoglobulin G 6.88 g/L; Immunoglobulin A 1.66 g/L; Immunoglobulin M 0.52 g/L; Beta 2 Microglobulin 2.01 µg/mL; Lactate Dehydrogenase 3.4 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 2.33 ×10⁹/L; Platelets 241 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 6.5 g/dL; Glucose 6.16 mmol/L.

Other clinical attributes
- Day -7: Weight: 90 kg; Height: 166 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2140_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -7 days.
- Sample MMRF_2140_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -7 days.
